Somatic mutation profile of tumor specimen MP2PRT-PAPMJA-TMP1-A (aliquot MP2PRT-PAPMJA-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPMJA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.7 years (1,346 days).
Specimen MP2PRT-PAPMJA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dca3f19-bad9-468d-841b-baf2476404a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPMJA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPMJA-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/152ad635-916c-4b43-ac69-3ce51e9d63a6

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, In Frame Del 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1412756906, COSV54842683; called by muse, mutect2
- BCL6 | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 232/511 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs763470720; called by muse, mutect2, varscan2
- MMEL1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 67/525 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.097); catalogued as rs1226789469, COSV56522164; called by muse, mutect2, varscan2
- RASA1 | c.1760A>G p.N587S | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.101); catalogued as rs894219060, COSV57192351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3TC2 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs201789838; ClinVar: uncertain significance; called by muse, mutect2
- TRPV4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 159/496 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.2); catalogued as rs767169716, COSV55682549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5D | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1377330756, COSV54776231; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 19/326 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- DOT1L | c.668T>C p.F223S | Missense Mutation (SNP) | VAF 35/399 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FANCM | c.2792A>G p.N931S | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HEG1 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGHV3-53 | c.345_346delinsCTTGGG p.R116Lfs*? | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by pindel, varscan2*
- IGKV1D-8 | c.260_274delinsCCT p.S87_D92delinsTY | In Frame Del (DEL) | VAF 38/77 reads (49%) | called by pindel, varscan2*
- NSD2 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.5098C>A p.L1700I | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, varscan2
- TTN | c.32503G>T p.V10835F (on ENST00000591111; = p.V9908F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/354 reads (23%) | PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF479 | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ACOX3 | c.699G>A p.P233= | Silent (SNP) | VAF 33/439 reads (8%) | catalogued as rs759340835, COSV62712778, COSV62713949; called by muse, mutect2
- PSG6 | c.1065G>A p.A355= | Silent (SNP) | VAF 76/319 reads (24%) | catalogued as rs755420910, COSV51831603; called by muse, mutect2, varscan2
- PTPN21 | c.3228A>G p.G1076= | Silent (SNP) | VAF 22/242 reads (9%) | catalogued as COSV60848854; called by muse, mutect2
